Somatic mutation profile of tumor specimen ALCH-ADN7-TTP1-A (aliquot ALCH-ADN7-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-ADN7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.0 years (21,567 days).
Specimen ALCH-ADN7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a4435c0-ad3b-4337-9657-3079a7e0672d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADN7-NB1-A (Blood Derived Normal), aliquot ALCH-ADN7-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4c4c53d-8ef6-434b-8cc1-a71a84f0b980

The open-access MAF lists 113 somatic variants for this specimen: 68 protein-altering or splice-affecting, 25 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 25, Intron 9, Nonsense Mutation 6, 5'UTR 6, RNA 3, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 328/1100 reads (30%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADCY10 | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV63240983; called by muse, mutect2
- CACNB2 | c.367G>A p.V123I (on ENST00000324631 / NM_201596.3; = p.V68I on NM_000724.4) | Missense Mutation (SNP) | VAF 106/1438 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1488807984; called by muse, mutect2
- CALD1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 30/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773676427, COSV62647273; called by muse, mutect2
- CLN3 | c.256G>A p.V86I (on ENST00000360019 / NM_001286104.2; = p.V110I on NM_000086.2) | Missense Mutation (SNP) | VAF 91/1198 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs781534624, COSV100343317; called by muse, mutect2
- DNAH3 | c.5845C>G p.L1949V | Missense Mutation (SNP) | VAF 54/1036 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.114); catalogued as COSV104372434; called by muse, mutect2
- EIF2A | c.1710del p.E571Kfs*23 | Frame Shift Del (DEL) | VAF 64/348 reads (18%) | catalogued as COSV56407115; called by mutect2, pindel, varscan2
- FAM216B | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 51/452 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs200110453, COSV58271454; called by muse, mutect2, varscan2
- FAT1 | c.13339G>A p.E4447K | Missense Mutation (SNP) | VAF 48/622 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.427); catalogued as rs1423542665; called by muse, mutect2
- MARK4 | c.1894G>A p.E632K (on ENST00000262891 / NM_001199867.2; = p.L658= on NM_031417.4) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV53463720; called by muse, mutect2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 237/1100 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDHA8 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 64/1240 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100970403, COSV65334844; called by muse, mutect2
- PCDHGB5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 66/1249 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756009874, COSV53966911; called by muse, mutect2
- PLXNC1 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 39/588 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1360830855; called by muse, mutect2
- PTAFR | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs1268668884; called by muse, mutect2
- RTP1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV56618134; called by muse, mutect2, varscan2
- SCRIB | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs750570969, COSV57583518; called by muse, mutect2, varscan2
- SLC16A4 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 25/192 reads (13%) | catalogued as COSV63917363; called by muse, mutect2, varscan2
- TTLL7 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146805080, COSV53083293; called by muse, mutect2
- UNC5B | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780005887, COSV58974322; called by muse, mutect2, varscan2
- ZFPM1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 38/407 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.174); catalogued as rs754801110; called by muse, mutect2
- ZNF366 | c.1812C>A p.F604L | Missense Mutation (SNP) | VAF 119/683 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV59218597; called by muse, mutect2, varscan2
- ZNF426 | c.1412C>G p.T471S | Missense Mutation (SNP) | VAF 24/407 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.905); catalogued as rs1219549949, COSV53470221; called by muse, mutect2
- ABCC4 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ALMS1 | c.9193G>C p.D3065H | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2
- ANKRD53 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 66/1231 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2
- ASPM | c.8438C>T p.S2813F | Missense Mutation (SNP) | VAF 56/909 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- B4GALT4 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 82/1192 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2
- BNC1 | c.2181G>C p.K727N | Missense Mutation (SNP) | VAF 23/572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCNF | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CDC14C | c.788T>C p.V263A (on ENST00000428251; = p.V156A on NM_152627.3) | Missense Mutation (SNP) | VAF 28/747 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2
- COG2 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 37/859 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2
- COQ8A | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 66/1158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CSE1L | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPY19L3 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 58/856 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.518); called by muse, mutect2
- DYRK1A | c.1673T>A p.V558E | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2
- EMILIN3 | c.2001_2002insT p.V668Cfs*23 | Frame Shift Ins (INS) | VAF 66/349 reads (19%) | called by mutect2, pindel, varscan2
- FAM221B | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 58/331 reads (18%) | called by muse, mutect2, varscan2
- FCHSD2 | c.1527+2T>C p.X509_splice | Splice Site (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- FLT1 | c.3835del p.S1279Vfs*63 | Frame Shift Del (DEL) | VAF 223/1483 reads (15%) | called by mutect2, pindel, varscan2
- GPATCH3 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- HAS2 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 40/555 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFT140 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2
- KIAA1109 | c.12497G>A p.G4166E | Missense Mutation (SNP) | VAF 31/481 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTK | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2
- MAGEF1 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- MAP3K3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 43/983 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MED12L | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPDZ | c.5639G>A p.G1880E (on ENST00000319217 / NM_001330637.2; = p.G1851E on NM_003829.5) | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MYPN | c.3946G>T p.E1316* | Nonsense Mutation (SNP) | VAF 274/1355 reads (20%) | called by muse, mutect2, varscan2
- NCAPD2 | c.3999dup p.D1334Rfs*3 | Frame Shift Ins (INS) | VAF 95/458 reads (21%) | called by mutect2, pindel, varscan2
- NRK | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.327); called by muse, mutect2
- PACSIN1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 37/680 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2
- PDCD11 | c.3230C>G p.S1077C | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLPPR3 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLXND1 | c.3631C>T p.H1211Y | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- POMGNT1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 25/688 reads (4%) | PolyPhen probably damaging (0.975); called by muse, mutect2
- PPP2R2A | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- RAB3A | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 28/480 reads (6%) | called by muse, mutect2
- RHBDD2 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 149/1293 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- RNF11 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 27/536 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- SIRT6 | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 113/609 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TBC1D8 | c.2324C>A p.S775Y | Missense Mutation (SNP) | VAF 51/758 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- TRMT5 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2
- USE1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- VARS1 | c.2862G>A p.W954* | Nonsense Mutation (SNP) | VAF 19/368 reads (5%) | called by muse, mutect2
- VDAC1 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 24/515 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ZYG11B | c.1981T>G p.F661V | Missense Mutation (SNP) | VAF 146/1290 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- AC073610.2 | c.546G>A p.L182= | Silent (SNP) | VAF 38/1322 reads (3%) | called by muse, mutect2
- ACTL7B | c.195C>T p.Y65= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as COSV65927038; called by muse, mutect2, varscan2
- AHNAK2 | c.11208C>G p.L3736= | Silent (SNP) | VAF 48/997 reads (5%) | called by muse, mutect2
- BEX2 | c.51C>T p.V17= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as COSV65501248; called by muse, mutect2
- CCDC88B | c.3823C>A p.R1275= | Silent (SNP) | VAF 32/230 reads (14%) | called by muse, mutect2, varscan2
- CLSTN1 | c.2688G>A p.G896= (on ENST00000377298 / NM_001009566.3; = p.G886= on NM_014944.4) | Silent (SNP) | VAF 40/920 reads (4%) | called by muse, mutect2
- CYP2A6 | c.669C>T p.F223= | Silent (SNP) | VAF 26/247 reads (11%) | catalogued as COSV56533657; called by muse, mutect2
- EPB41L3 | c.99G>T p.V33= | Silent (SNP) | VAF 102/493 reads (21%) | catalogued as rs562661014; called by muse, mutect2, varscan2
- FBN3 | c.6687C>T p.I2229= | Silent (SNP) | VAF 15/257 reads (6%) | catalogued as rs200143055; called by muse, mutect2
- GDF5 | c.918G>A p.S306= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs771196534; called by muse, varscan2
- GOLGA8M | c.414G>A p.L138= | Silent (SNP) | VAF 140/2220 reads (6%) | catalogued as rs1378959224; called by muse, mutect2
- NAV3 | c.348C>T p.I116= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as rs949496936; called by muse, mutect2
- ODAPH | c.216C>T p.F72= | Silent (SNP) | VAF 344/1480 reads (23%) | called by mutect2, varscan2
- POU2F3 | c.336A>T p.L112= | Silent (SNP) | VAF 48/472 reads (10%) | called by muse, mutect2
- PPP1R9B | c.975C>A p.V325= | Silent (SNP) | VAF 74/471 reads (16%) | called by muse, mutect2, varscan2
- RPN1 | c.18C>T p.A6= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs777405053, COSV56191145; called by muse, mutect2, varscan2
- RTL3 | c.123G>A p.Q41= | Silent (SNP) | VAF 20/693 reads (3%) | called by muse, mutect2
- SIAE | c.24C>T p.L8= | Silent (SNP) | VAF 70/879 reads (8%) | catalogued as rs372778156; called by muse, mutect2
- SLC1A5 | c.1429C>T p.L477= | Silent (SNP) | VAF 43/379 reads (11%) | called by muse, mutect2
- SLC52A1 | c.349C>T p.L117= | Silent (SNP) | VAF 16/458 reads (3%) | catalogued as COSV54693864; called by muse, mutect2
- SPG11 | c.3546C>T p.F1182= | Silent (SNP) | VAF 27/604 reads (4%) | catalogued as rs780928415, COSV99968125; ClinVar: likely benign; called by muse, mutect2
- SPOCD1 | c.1944C>T p.L648= | Silent (SNP) | VAF 50/734 reads (7%) | catalogued as COSV57100921; called by muse, mutect2
- TENM3 | c.8088C>T p.I2696= | Silent (SNP) | VAF 46/555 reads (8%) | catalogued as rs752922208; called by muse, mutect2
- TMEM201 | c.132G>A p.T44= | Silent (SNP) | VAF 38/689 reads (6%) | catalogued as rs772412947; called by muse, mutect2
- UGT2A3 | c.1443C>T p.L481= | Silent (SNP) | VAF 52/808 reads (6%) | called by muse, mutect2
- AC139491.1 | n.540G>A | RNA (SNP) | VAF 51/409 reads (12%) | catalogued as rs982041230; called by muse, mutect2, varscan2
- ACYP1 | c.-4G>C | 5'UTR (SNP) | VAF 30/428 reads (7%) | called by muse, mutect2
- ADORA1 | c.-173G>A | 5'UTR (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
- ANKHD1 | c.1782+7536_1782+7542del | Intron (DEL) | VAF 80/636 reads (13%) | called by mutect2, pindel
- ANKRD20A5P | n.168G>C | RNA (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- ATPAF2 | c.324+26G>T | Intron (SNP) | VAF 36/748 reads (5%) | called by muse, mutect2
- C8G | c.596-36del | Intron (DEL) | VAF 82/403 reads (20%) | called by mutect2, pindel, varscan2
- CSNK1E | c.886-2092G>C | Intron (SNP) | VAF 51/471 reads (11%) | called by muse, mutect2, varscan2
- DDX39B | c.735+898C>A | Intron (SNP) | VAF 18/397 reads (5%) | called by muse, mutect2
- ERAP1 | c.*288C>T | 3'UTR (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ETV1 | c.45+288dup | Intron (INS) | VAF 335/1325 reads (25%) | catalogued as rs1227319647; called by mutect2, pindel, varscan2
- HECTD4 | c.3442-23C>T | Intron (SNP) | VAF 26/300 reads (9%) | catalogued as COSV61178583, COSV61179490; called by muse, mutect2
- MIR543 | n.45C>T | RNA (SNP) | VAF 16/127 reads (13%) | catalogued as rs745784066; called by muse, mutect2, varscan2
- MT1X | c.-32G>A | 5'UTR (SNP) | VAF 172/411 reads (42%) | catalogued as COSV66777982, COSV66778128; called by muse, mutect2, varscan2
- MYL3 | c.-18C>T | 5'UTR (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- MYO6 | c.-19C>T | 5'UTR (SNP) | VAF 84/1326 reads (6%) | catalogued as rs746580223, COSV100889310; called by muse, mutect2
- PCNX2 | c.2864-1950C>A | Intron (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- RNASEH2B | c.822+47G>C | Intron (SNP) | VAF 25/389 reads (6%) | called by muse, mutect2
- SULT1A1 | c.-16C>G | 5'UTR (SNP) | VAF 32/265 reads (12%) | called by muse, mutect2, varscan2
- TSHZ2 | c.*1887G>A | 3'UTR (SNP) | VAF 42/1303 reads (3%) | catalogued as rs900004840; called by muse, mutect2
